Gene-level copy-number profile of tumor specimen TCGA-CV-6940-01A from TCGA case TCGA-CV-6940, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 80.4 years (29,382 days).
Specimen TCGA-CV-6940-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.c4d75d13-d35c-4987-961a-77419e9dedc7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-6940-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9517eeac-e8c9-4bb3-9cf2-f4d85f46f11a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 267; copy number 1: 927; copy number 2: 9,375; copy number 3: 17,167; copy number 4: 23,221; copy number 5: 4,558; copy number 6: 2,663; copy number 8: 1,160; copy number 11: 13; copy number 15: 178; copy number 17: 135; copy number 20: 134; copy number 26: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-6940-01A-11D-1910-01): tumor purity 0.6, ploidy 3.65, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 267 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,058,771–30,990,572, 125 genes (broad region; genes not listed).
- chr9:37,915,898–43,045,120, 142 genes (within-gene range 0–15) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 466 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–21,031,640, 269 genes, copy number 17–20 (within-gene range 0–20) (broad region; genes not listed).
- chr9:33,706,679–38,068,687, 178 genes, copy number 15 (within-gene range 0–15) (broad region; genes not listed).
- chr9:63,581,254–63,762,824, 6 genes, copy number 26: AL591438.1, AL591438.2, CDRT15P7, AL772155.1, AL772155.2, MYO5BP3.
- chr18:5,132,749–5,630,700, 13 genes, copy number 11 (within-gene range 8–11): BOD1P2, AKAIN1, AP005380.1, AP001496.4, AP001496.2, LINC00526, LINC00667, AP001496.3, ZBTB14, AP001496.1, AP005671.1, EPB41L3, AP005059.2.

Autosomal genes at a single copy (total copy number 1): 25. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
